Somatic mutation profile of tumor specimen ALCH-B1ZS-TTP1-A (aliquot ALCH-B1ZS-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1ZS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 79.6 years (29,079 days).
Specimen ALCH-B1ZS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf5bf353-b13b-4a1c-8801-e87cda884148.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ZS-NB1-A (Blood Derived Normal), aliquot ALCH-B1ZS-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5abf83a7-559d-4a9d-b95e-bf8d7f9734f7

The open-access MAF lists 480 somatic variants for this specimen: 323 protein-altering or splice-affecting, 97 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 97, Intron 32, Nonsense Mutation 25, 5'UTR 11, Splice Site 9, RNA 9, 3'UTR 5, Frame Shift Del 5, In Frame Del 3, Frame Shift Ins 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 18/140 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 72/201 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 96/241 reads (40%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1021G>T p.D341Y (on ENST00000272895 / NM_173076.3; = p.D23Y on NM_015657.3) | Missense Mutation (SNP) | VAF 84/338 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs1342817633; called by muse, mutect2, varscan2
- ABCB4 | c.818A>T p.N273I | Missense Mutation (SNP) | VAF 323/840 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV104378834; called by muse, mutect2, varscan2
- ADAM2 | c.2175-2A>T p.X725_splice | Splice Site (SNP) | VAF 33/201 reads (16%) | catalogued as COSV55862974; called by muse, mutect2, varscan2
- ADAMTS12 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 33/316 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100711320; called by muse, mutect2, varscan2
- ADAMTS20 | c.5696C>G p.P1899R | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754979211; called by muse, mutect2, varscan2
- ALCAM | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60250848; called by muse, mutect2, varscan2
- ANGEL2 | c.642+1G>C p.X214_splice | Splice Site (SNP) | VAF 34/116 reads (29%) | catalogued as COSV64738023; called by muse, mutect2
- ANO3 | c.1732C>G p.Q578E | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV99881271; called by muse, mutect2
- ARID1A | c.4609C>T p.Q1537* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV61372580; called by muse, mutect2
- ARID1A | c.4994-2A>G p.X1665_splice | Splice Site (SNP) | VAF 31/138 reads (22%) | catalogued as COSV100253620, COSV61377871; called by muse, mutect2, varscan2
- ARMCX2 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs782236145, COSV100168042, COSV100168314, COSV57529376; called by muse, mutect2, varscan2
- ASTN2 | c.1526G>T p.W509L (on ENST00000313400 / NM_001365069.1; = p.W458L on NM_014010.5) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV100528976; called by muse, mutect2, varscan2
- ASXL3 | c.1298T>A p.I433K | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs371946333; called by muse, mutect2, varscan2
- ATF7IP | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV53776122; called by muse, mutect2, varscan2
- ATP12A | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1384284866, COSV54518322, COSV54518839; called by muse, mutect2
- ATP2C2 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV52298724; called by muse, mutect2, varscan2
- BNIP5 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 155/462 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as rs752431397, COSV71325274; called by muse, mutect2, varscan2
- C2orf16 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV68842176; called by muse, mutect2
- CARD11 | c.2407G>T p.V803F | Missense Mutation (SNP) | VAF 207/438 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV62754306; called by muse, varscan2
- CASKIN2 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58690238; called by muse, mutect2, varscan2
- CCDC172 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV60937993; called by muse, mutect2, varscan2
- CCDC175 | c.654G>C p.E218D | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1204295457; called by muse, mutect2
- CD96 | c.695A>G p.H232R (on ENST00000283285 / NM_198196.3; = p.H216R on NM_005816.5) | Missense Mutation (SNP) | VAF 131/425 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51922275; called by muse, mutect2, varscan2
- CDYL | c.1393G>A p.A465T (on ENST00000328908 / NM_001368125.1; = p.A411T on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV59359591; called by muse, mutect2, varscan2
- CENPF | c.8104C>T p.R2702W | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs376987914; called by muse, mutect2, varscan2
- CIITA | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs766316610; called by muse, mutect2, varscan2
- CLNK | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs769286486; called by muse, mutect2
- COL11A1 | c.4504C>T p.P1502S | Missense Mutation (SNP) | VAF 40/564 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as COSV62172275; called by muse, mutect2
- COL11A1 | c.3176C>A p.P1059Q | Missense Mutation (SNP) | VAF 178/519 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV62172423, COSV62198672; called by muse, mutect2, varscan2
- COL3A1 | c.3590G>A p.C1197Y | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.687); catalogued as COSV58581159; called by muse, mutect2
- COL6A6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as rs889564954, COSV62017697; called by muse, mutect2, varscan2
- COL8A1 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53734121; called by muse, mutect2, varscan2
- CPLX3 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV59001866; called by muse, mutect2, varscan2
- CRYBB3 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 170/473 reads (36%) | catalogued as rs1250184223; called by muse, mutect2, varscan2
- CYP2C18 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV53672342; called by muse, mutect2
- CYP2W1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs547288712; called by muse, mutect2, varscan2
- DAW1 | c.1100A>G p.K367R | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV59367561; called by muse, mutect2
- DDR2 | c.2464G>C p.D822H | Missense Mutation (SNP) | VAF 215/886 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as COSV63371320; called by muse, mutect2, varscan2
- DGKB | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV99340093; called by muse, mutect2
- DLGAP4 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs199556260; called by muse, mutect2
- DMD | c.7184C>T p.A2395V | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58923464; called by muse, mutect2
- DNAJC11 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 57/330 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs748488397; called by muse, mutect2, varscan2
- DPP10 | c.531C>A p.D177E | Missense Mutation (SNP) | VAF 34/504 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV100070549; called by muse, mutect2
- EPRS1 | c.1498A>G p.I500V | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1466694400; called by muse, mutect2, varscan2
- EPS8 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1447663801; called by muse, mutect2, varscan2
- ERICH3 | c.3466A>G p.I1156V | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs778078125; called by muse, mutect2, varscan2
- ERO1B | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.833); catalogued as COSV59241843; called by muse, mutect2, varscan2
- FAAH | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 206/441 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV54543041; called by muse, mutect2, varscan2
- FAM47A | c.2093G>C p.W698S | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV100650117; called by muse, mutect2, varscan2
- FAM47B | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61456729; called by muse, mutect2, varscan2
- FUT5 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as rs757206885; called by muse, mutect2, varscan2
- GPR142 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs199997380, COSV59518721, COSV59519491, COSV99046011; called by muse, mutect2, varscan2
- GPR158 | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 171/485 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs951022903; called by muse, mutect2, varscan2
- H2BC11 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as rs376935770; called by muse, mutect2, varscan2
- HIVEP1 | c.2930A>G p.H977R | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485211951, COSV65103083; called by muse, mutect2, varscan2
- HPD | c.1160A>T p.N387I | Missense Mutation (SNP) | VAF 116/337 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as rs751532063; called by muse, mutect2, varscan2
- HUWE1 | c.2299A>C p.M767L | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV99473242; called by muse, mutect2, varscan2
- IFNAR1 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54251544; called by muse, mutect2, varscan2
- IGFBP3 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs950133149; called by muse, mutect2, varscan2
- ITPKA | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs1354233027; called by mutect2, varscan2
- JAK1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.06); catalogued as rs532214548; called by muse, mutect2, varscan2
- KCNB2 | c.1706C>A p.A569E | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.049); catalogued as COSV101579031; called by muse, mutect2, varscan2
- KCNN1 | c.1319T>A p.V440E | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99716419; called by muse, mutect2, varscan2
- KLHL32 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV65113428; called by muse, mutect2, varscan2
- KRT31 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1426127423, COSV99289509; called by muse, mutect2, varscan2
- LAPTM5 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV53852371; called by muse, mutect2, varscan2
- LCOR | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 70/724 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs763362938, COSV63631668; called by muse, mutect2
- LIPI | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100754006; called by mutect2, varscan2
- LRRC66 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV58633994; called by muse, mutect2
- LRRTM4 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV69141610; called by muse, mutect2, varscan2
- LTBP4 | c.994+2T>A p.X332_splice (on ENST00000308370 / NM_001042544.1; = p.X295_splice on NM_003573.2) | Splice Site (SNP) | VAF 37/203 reads (18%) | catalogued as rs112704404; called by muse, mutect2, varscan2
- LY6L | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1293941893; called by muse, mutect2, varscan2
- MAGEC3 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100025890; called by muse, mutect2, varscan2
- MAP3K14 | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs1270528203; called by muse, mutect2
- MDGA2 | c.2966C>G p.A989G (on ENST00000399232 / NM_001113498.2; = p.A691G on NM_182830.4) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV62079969; called by muse, mutect2, varscan2
- ME3 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 27/161 reads (17%) | catalogued as rs200949546; called by muse, mutect2, varscan2
- MTA1 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58755648; called by muse, mutect2, varscan2
- MTUS2 | c.3006G>T p.K1002N | Missense Mutation (SNP) | VAF 16/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV70919490; called by muse, mutect2
- MUC5B | c.4767C>A p.Y1589* | Nonsense Mutation (SNP) | VAF 55/151 reads (36%) | catalogued as COSV71592137; called by muse, mutect2, varscan2
- MYH7B | c.1097_1099del p.N366del | In Frame Del (DEL) | VAF 33/319 reads (10%) | catalogued as rs1421621207; called by pindel, varscan2
- MYOM3 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.869); catalogued as rs145011026; called by muse, mutect2, varscan2
- N4BP2L2 | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV57229154, COSV57230220; called by muse, mutect2, varscan2
- NBPF11 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 122/714 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.636); catalogued as rs3992694; called by muse, varscan2
- NF1 | c.1641+1G>T p.X547_splice | Splice Site (SNP) | VAF 72/333 reads (22%) | catalogued as CS000896, COSV62197916, COSV62224048; called by muse, mutect2, varscan2
- NISCH | c.4051G>T p.V1351L | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs984475667; called by muse, mutect2, varscan2
- OR14C36 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV100507398; called by muse, mutect2, varscan2
- OR2G3 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV60680919; called by muse, mutect2, varscan2
- OR2M7 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1259533471, COSV58741034; called by muse, mutect2, varscan2
- OR4E2 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs763815002, COSV57731291; called by muse, mutect2, varscan2
- OR56B1 | c.569A>T p.N190I | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57722786; called by muse, mutect2, varscan2
- OR5K3 | c.688del p.E230Rfs*49 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV101051647; called by mutect2, pindel, varscan2
- OR5M8 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59116330; called by muse, mutect2, varscan2
- OR5T3 | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV57381965; called by muse, mutect2, varscan2
- PCDH11X | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV100006796; called by muse, mutect2, varscan2
- PDCD4 | c.573A>C p.L191F | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as rs1396521321; called by muse, mutect2, varscan2
- PEX16 | c.498C>G p.Y166* | Nonsense Mutation (SNP) | VAF 223/626 reads (36%) | catalogued as COSV53804257; called by muse, mutect2, varscan2
- PKHD1L1 | c.4702A>G p.I1568V | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs376070110; called by muse, mutect2, varscan2
- PLEK | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 43/250 reads (17%) | catalogued as COSV52251905; called by muse, mutect2, varscan2
- PLPPR4 | c.2053C>A p.R685S | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.341); catalogued as COSV64565667; called by muse, mutect2, varscan2
- PNMA3 | c.632dup p.A213Cfs*35 | Frame Shift Ins (INS) | VAF 58/341 reads (17%) | catalogued as rs1569523410; called by mutect2, pindel, varscan2
- PRB4 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV54400238; called by muse, varscan2
- PRPF4B | c.2249G>T p.C750F | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61785252; called by muse, mutect2, varscan2
- PSG2 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 166/715 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs1058464; called by muse, mutect2, varscan2
- PTCHD1 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 90/526 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs727504113, COSV65059472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRC | c.2532C>G p.F844L | Missense Mutation (SNP) | VAF 66/960 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV61415861; called by muse, mutect2
- RTL1 | c.2524C>A p.Q842K | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV66017444; called by muse, mutect2, varscan2
- RYR2 | c.9526G>T p.D3176Y | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs761272070; called by muse, mutect2, varscan2
- SCAF1 | c.2131G>C p.D711H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV62183297; called by muse, mutect2, varscan2
- SCAF1 | c.2613G>C p.E871D | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1172993594, COSV62182511; called by muse, mutect2, varscan2
- SCN4A | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 53/160 reads (33%) | catalogued as rs1346024466; called by muse, varscan2
- SIX4 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs1030551040; called by muse, mutect2, varscan2
- SLC15A4 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV57163816; called by muse, mutect2, varscan2
- SLC16A7 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 67/503 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs141923225; called by muse, mutect2, varscan2
- SLC17A6 | c.1514G>T p.W505L | Missense Mutation (SNP) | VAF 92/367 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54133328, COSV54136526; called by muse, mutect2, varscan2
- SLC17A9 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV64848681; called by muse, mutect2, varscan2
- SLC6A2 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 64/595 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54913743, COSV54925473; called by muse, mutect2, varscan2
- SLCO4A1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs571205330; called by muse, mutect2, varscan2
- SNRNP200 | c.2893G>C p.D965H | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV60492598; called by muse, mutect2
- SNX1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs138423671; called by muse, mutect2, varscan2
- SRBD1 | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs536689903; called by muse, mutect2, varscan2
- ST8SIA6 | c.975G>C p.L325F | Missense Mutation (SNP) | VAF 166/539 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.685); catalogued as COSV66472328; called by muse, mutect2, varscan2
- STK33 | c.1487C>G p.T496R | Missense Mutation (SNP) | VAF 225/830 reads (27%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.092); catalogued as rs376097595; called by muse, mutect2, varscan2
- STYXL2 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs200961284; called by muse, mutect2, varscan2
- SYT1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1306238645; called by muse, mutect2, varscan2
- THSD7A | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs769709844, COSV101448498; called by muse, mutect2, varscan2
- TMPRSS4 | c.1142A>T p.D381V | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359554977; called by muse, mutect2, varscan2
- TP53 | c.1044G>C p.L348F | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52730754, COSV52829880; called by muse, mutect2, varscan2
- TRGV3 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 97/265 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as rs375207744; called by muse, mutect2, varscan2
- TRIO | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 21/565 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1463408921; called by muse, mutect2
- TRIO | c.4388G>A p.R1463Q | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs373502206; called by muse, mutect2, varscan2
- TTN | c.91637T>C p.I30546T (on ENST00000591111; = p.I23122T on NM_003319.4) | Missense Mutation (SNP) | VAF 156/476 reads (33%) | PolyPhen possibly damaging (0.575); catalogued as rs1377093791; called by muse, mutect2, varscan2
- TUBGCP6 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs751022706; called by muse, mutect2, varscan2
- UNC13D | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs528245426; called by muse, mutect2, varscan2
- USP29 | c.2572G>T p.D858Y | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54140150, COSV54144117; called by muse, mutect2, varscan2
- ZFHX4 | c.8152G>T p.E2718* | Nonsense Mutation (SNP) | VAF 49/152 reads (32%) | catalogued as COSV50714576; called by muse, mutect2, varscan2
- ZNF469 | c.6506C>T p.P2169L (on ENST00000437464; = p.P2197L on NM_001367624.2) | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.071); catalogued as rs1476037808; called by muse, mutect2, varscan2
- ZNF521 | c.1633G>T p.G545W | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV64132138; called by muse, mutect2
- ZNF536 | c.3227C>T p.S1076F | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.278); catalogued as COSV62825810; called by muse, mutect2
- ZNF546 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61257330; called by muse, mutect2, varscan2
- ZNF716 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 42/212 reads (20%) | catalogued as COSV101348717; called by muse, varscan2
- ZNF804A | c.3224C>A p.P1075Q | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as rs1328821265, COSV56439267; called by muse, mutect2, varscan2
- ABCA13 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ABCB11 | c.2161T>C p.Y721H | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM21 | c.1115C>G p.A372G | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADAM22 | c.2287T>C p.Y763H | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- ADAMTSL1 | c.4650G>T p.M1550I | Missense Mutation (SNP) | VAF 107/224 reads (48%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- ADGRF4 | c.1466del p.F489Sfs*21 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, pindel
- AHCTF1 | c.1373A>G p.H458R (on ENST00000366508; = p.H432R on NM_015446.5) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ANKRD30A | c.1846G>C p.V616L (on ENST00000611781; = p.V560L on NM_052997.2) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ANKRD30B | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANO5 | c.1309A>T p.R437W | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APC2 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ASTN2 | c.801C>G p.S267R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- BATF | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BPIFB2 | c.548del p.G183Vfs*9 | Frame Shift Del (DEL) | VAF 43/235 reads (18%) | called by mutect2, pindel, varscan2
- C2CD4D | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAAP1 | c.977C>G p.P326R | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CALCR | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- CAMK2B | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 10/370 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.404); called by muse, mutect2
- CARMIL1 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.96); called by muse, mutect2
- CATSPERE | c.2404-1G>C p.X802_splice | Splice Site (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- CCDC142 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 75/206 reads (36%) | called by muse, mutect2, varscan2
- CCL23 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 103/369 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEBPD | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- CEP41 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 52/766 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2
- CLIP4 | c.1420T>C p.S474P | Missense Mutation (SNP) | VAF 96/647 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CLVS2 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CPA2 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 164/409 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CR2 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 40/738 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CROCC2 | c.3369G>T p.Q1123H | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, varscan2
- CSMD2 | c.1465A>G p.S489G | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYRIA | c.317T>G p.L106* | Nonsense Mutation (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- DCC | c.4145C>A p.A1382D | Missense Mutation (SNP) | VAF 119/469 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCDC1 | c.1880G>C p.W627S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX11 | c.1995C>G p.S665R | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DNAH6 | c.10738C>T p.P3580S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DNAH8 | c.10189C>A p.P3397T | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAI1 | c.614del p.P205Lfs*31 | Frame Shift Del (DEL) | VAF 95/793 reads (12%) | called by mutect2, varscan2
- DSCAM | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- DSPP | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 124/322 reads (39%) | called by muse, mutect2, varscan2
- DST | c.18783T>G p.H6261Q (on ENST00000361203 / NM_001374722.1; = p.H3958Q on NM_015548.5) | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); called by muse, mutect2
- DTNA | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 60/906 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- DTX2 | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP22 | c.449T>G p.L150R | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EFHB | c.2429G>T p.C810F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- EMG1 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 127/374 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ESYT3 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.253); called by muse, varscan2
- FAAP100 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM217B | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FASN | c.1494G>A p.G498= | Splice Region (SNP) | VAF 103/328 reads (31%) | called by muse, mutect2, varscan2
- FGF12 | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- FOXJ1 | c.490A>T p.T164S | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FSIP2 | c.10205C>A p.A3402D | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GCM2 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 253/816 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- GJA4 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GOLGA6L4 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 4/6 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by mutect2, varscan2
- GOLGA7 | c.364_366+43del p.X122_splice | Splice Site (DEL) | VAF 14/180 reads (8%) | called by mutect2, pindel
- GPR27 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.942); called by muse, mutect2
- GRID1 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- GSR | c.1117G>T p.V373F | Missense Mutation (SNP) | VAF 103/793 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- HCN1 | c.1352dup p.N451Kfs*2 | Frame Shift Ins (INS) | VAF 8/73 reads (11%) | called by mutect2, pindel
- HEATR9 | c.1097T>A p.L366Q | Missense Mutation (SNP) | VAF 139/575 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HERC2 | c.4631G>A p.R1544K | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHLA2 | c.223T>A p.Y75N | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- HYAL3 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 106/251 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICA1 | c.1414G>T p.G472W | Missense Mutation (SNP) | VAF 169/405 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDI1 | c.703_705dup p.E235dup | In Frame Ins (INS) | VAF 18/134 reads (13%) | called by mutect2, pindel, varscan2
- IER3 | c.452A>G p.Q151R | Missense Mutation (SNP) | VAF 129/475 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGKV3-15 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 98/1162 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.585); called by muse, mutect2
- IKZF1 | c.1430A>G p.Y477C | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INA | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IQGAP1 | c.4145G>T p.R1382L | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ITGAX | c.962C>A p.A321D | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- JAG1 | c.3331A>G p.T1111A | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2
- KLF14 | c.776T>A p.L259H | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL25 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- KLK15 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMO | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP20-3 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- KRTAP26-1 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRTAP9-9 | c.236C>A p.T79N | Missense Mutation (SNP) | VAF 138/486 reads (28%) | SIFT tolerated (0.14); called by muse, mutect2, varscan2
- LGR5 | c.806T>A p.I269N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIPA | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 214/602 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LKAAEAR1 | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- LRFN5 | c.871C>A p.R291S | Missense Mutation (SNP) | VAF 132/396 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRRC37A3 | c.3938G>T p.R1313L | Missense Mutation (SNP) | VAF 276/996 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.132); called by muse, varscan2
- MAP1S | c.3094C>T p.Q1032* | Nonsense Mutation (SNP) | VAF 56/300 reads (19%) | called by muse, mutect2, varscan2
- MDGA2 | c.1480G>T p.G494* (on ENST00000399232 / NM_001113498.2; = p.G196* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- MFSD3 | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2
- MINDY3 | c.455T>A p.L152* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- MSMB | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MSX2 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTR | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 146/660 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH13 | c.1665T>A p.Y555* | Nonsense Mutation (SNP) | VAF 83/210 reads (40%) | called by muse, mutect2, varscan2
- MYH15 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 56/319 reads (18%) | called by muse, mutect2, varscan2
- MYH9 | c.2759T>C p.L920P | Missense Mutation (SNP) | VAF 161/559 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NBEAL2 | c.8207G>C p.R2736P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NCAM2 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- NCAM2 | c.1492A>T p.S498C | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- NRXN2 | c.172C>A p.R58S | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NUP205 | c.3760C>A p.L1254I | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- OBSCN | c.10999G>T p.G3667* | Nonsense Mutation (SNP) | VAF 57/463 reads (12%) | called by muse, mutect2, varscan2
- OR12D2 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.208); called by muse, mutect2
- OR2A14 | c.770C>A p.T257K | Missense Mutation (SNP) | VAF 261/593 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- OR2D3 | c.109T>A p.L37M | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2
- OR2G6 | c.243G>T p.L81F | Missense Mutation (SNP) | VAF 79/565 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OR2J1 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 68/482 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.116); called by muse, mutect2
- OR2T1 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- OR52N5 | c.681C>A p.Y227* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- OR5A1 | c.75A>T p.E25D | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- OR5W2 | c.49A>T p.I17F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR8G5 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 53/397 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- OTOGL | c.6649T>A p.Y2217N (on ENST00000547103; = p.Y2208N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- P2RY10 | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 74/196 reads (38%) | called by muse, mutect2, varscan2
- PCDHA1 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB15 | c.693G>T p.L231F | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.209); called by muse, mutect2
- PCLO | c.13034G>A p.S4345N | Missense Mutation (SNP) | VAF 147/377 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PDGFC | c.101_103del p.S34del | In Frame Del (DEL) | VAF 39/103 reads (38%) | called by mutect2, pindel, varscan2
- PDZD7 | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- PDZRN3 | c.2259C>A p.D753E | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLCL1 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POPDC2 | c.189C>A p.C63* | Nonsense Mutation (SNP) | VAF 134/481 reads (28%) | called by muse, mutect2, varscan2
- PPEF2 | c.851T>C p.I284T | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- PPFIA3 | c.3425_3426dup p.T1143* | Frame Shift Ins (INS) | VAF 36/288 reads (13%) | called by mutect2, varscan2
- PRIM1 | c.258C>A p.H86Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.186); called by muse, mutect2
- PRLR | c.1154A>T p.N385I | Missense Mutation (SNP) | VAF 84/650 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PSD | c.1210T>A p.C404S | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RAPGEF2 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- RASGRP2 | c.1568A>T p.Y523F | Missense Mutation (SNP) | VAF 168/525 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- RBMXL3 | c.305del p.G102Afs*174 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- RELN | c.2308C>T p.L770F | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- RPS6KA2 | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPO2 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAFB | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- SAGE1 | c.2488C>G p.Q830E | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- SAMD15 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SARDH | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by mutect2, varscan2
- SETDB1 | c.3130-2A>T p.X1044_splice | Splice Site (SNP) | VAF 48/306 reads (16%) | called by muse, varscan2
- SETDB1 | c.3130-1G>T p.X1044_splice | Splice Site (SNP) | VAF 46/304 reads (15%) | called by muse, varscan2
- SETDB1 | c.3130G>T p.D1044Y | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); called by muse, varscan2
- SFRP1 | c.655_657del p.E219del | In Frame Del (DEL) | VAF 50/158 reads (32%) | called by mutect2, pindel, varscan2
- SHANK1 | c.5029G>T p.E1677* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- SHPRH | c.813A>C p.Q271H | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC17A6 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SLC37A3 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- SLC41A2 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SLC49A4 | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2
- SLC4A2 | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SLC7A1 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.142); called by muse, mutect2
- SMU1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 44/832 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.144); called by muse, mutect2
- SNAPC4 | c.2361C>A p.S787R | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNRPD3 | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SPATA31D1 | c.1732G>C p.V578L | Missense Mutation (SNP) | VAF 28/511 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2
- SPEM2 | c.953C>G p.T318R | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SPI1 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- SSRP1 | c.1661A>G p.Y554C | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- TEX51 | c.203G>C p.R68P (on ENST00000643416; = p.R50P on NM_001322244.2) | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- TFAP2B | c.914T>G p.V305G | Missense Mutation (SNP) | VAF 182/629 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM132E | c.1848C>A p.H616Q (on ENST00000321639; = p.H706Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TMEM132E | c.2098G>A p.A700T (on ENST00000321639; = p.A790T on NM_001304438.2) | Missense Mutation (SNP) | VAF 152/507 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TNXB | c.3052C>A p.Q1018K | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- TOP2B | c.4534A>C p.K1512Q (on ENST00000264331 / NM_001330700.2; = p.K1507Q on NM_001068.3) | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TOPAZ1 | c.4255G>C p.E1419Q | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TPTE | c.1294A>G p.K432E (on ENST00000618007 / NM_199261.4; = p.K414E on NM_199259.4) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TPTE | c.1396G>T p.V466L (on ENST00000618007 / NM_199261.4; = p.V448L on NM_199259.4) | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VPS13B | c.10400C>G p.A3467G | Missense Mutation (SNP) | VAF 72/520 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- WDFY4 | c.8156T>A p.L2719Q | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR62 | c.1546C>A p.L516M | Missense Mutation (SNP) | VAF 89/419 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- WSCD2 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WWP2 | c.160A>T p.K54* | Nonsense Mutation (SNP) | VAF 50/357 reads (14%) | called by muse, mutect2, varscan2
- XDH | c.3601G>T p.V1201F | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ZC3H7A | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFHX3 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZFHX4 | c.6886A>G p.K2296E | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZFR | c.3155G>A p.R1052K | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ZNF470 | c.1204T>A p.C402S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF559 | c.390A>T p.K130N | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF613 | c.934G>T p.G312* (on ENST00000293471 / NM_001031721.4; = p.G276* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 36/314 reads (11%) | called by muse, mutect2, varscan2
- ZNF738 | c.186A>T p.K62N | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2
- ZNF841 | c.960G>T p.K320N (on ENST00000426391 / NM_001369830.1; = p.K436N on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- A2M | c.2586A>G p.P862= | Silent (SNP) | VAF 19/440 reads (4%) | catalogued as rs776292253; called by muse, mutect2
- ADAMTS12 | c.444G>A p.Q148= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as rs756748274; called by muse, mutect2, varscan2
- AMPH | c.27C>T p.F9= | Silent (SNP) | VAF 65/166 reads (39%) | catalogued as rs1331672559; called by muse, mutect2, varscan2
- ATP8A2 | c.3507T>G p.V1169= | Silent (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- B3GALT5 | c.327G>A p.V109= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1288483102, COSV58197997; called by muse, mutect2, varscan2
- BRINP3 | c.1494A>G p.K498= | Silent (SNP) | VAF 124/555 reads (22%) | called by muse, mutect2, varscan2
- C18orf54 | c.76C>T p.L26= | Silent (SNP) | VAF 49/212 reads (23%) | called by muse, mutect2, varscan2
- C1orf94 | c.708C>T p.V236= (on ENST00000488417 / NM_001134734.2; = p.V46= on NM_032884.5) | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as COSV100974821; called by muse, mutect2
- CARD18 | c.42C>A p.I14= | Silent (SNP) | VAF 25/218 reads (11%) | called by muse, mutect2
- CBY2 | c.126A>G p.L42= | Silent (SNP) | VAF 58/152 reads (38%) | called by muse, mutect2, varscan2
- CD1A | c.732G>A p.Q244= | Silent (SNP) | VAF 108/484 reads (22%) | called by muse, mutect2, varscan2
- CDH11 | c.96G>T p.R32= | Silent (SNP) | VAF 36/245 reads (15%) | catalogued as rs751506849; called by muse, mutect2, varscan2
- CLEC4F | c.435C>A p.T145= | Silent (SNP) | VAF 121/333 reads (36%) | called by muse, mutect2, varscan2
- COL22A1 | c.2217C>T p.F739= | Silent (SNP) | VAF 33/278 reads (12%) | called by muse, mutect2, varscan2
- CTNND1 | c.1932G>A p.V644= (on ENST00000399050 / NM_001085458.2; = p.V638= on NM_001331.3) | Silent (SNP) | VAF 51/211 reads (24%) | catalogued as COSV62385834; called by muse, mutect2, varscan2
- CTSW | c.204C>T p.H68= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, varscan2
- CYP26B1 | c.897C>T p.A299= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as rs753232429; called by muse, mutect2
- DEGS1 | c.549G>A p.T183= | Silent (SNP) | VAF 131/503 reads (26%) | catalogued as rs369825210, COSV60378495; called by muse, mutect2, varscan2
- DPEP2 | c.915G>A p.K305= | Silent (SNP) | VAF 31/186 reads (17%) | catalogued as COSV52053809; called by muse, mutect2, varscan2
- ENPP2 | c.87T>C p.T29= | Silent (SNP) | VAF 32/211 reads (15%) | called by muse, mutect2, varscan2
- ESF1 | c.882T>C p.D294= | Silent (SNP) | VAF 28/344 reads (8%) | called by muse, mutect2
- FIGLA | c.213C>T p.N71= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs781849225; called by muse, mutect2, varscan2
- FXR1 | c.351A>G p.Q117= | Silent (SNP) | VAF 402/524 reads (77%) | called by muse, mutect2, varscan2
- GABRB3 | c.1152C>A p.G384= | Silent (SNP) | VAF 12/255 reads (5%) | called by muse, mutect2
- GDF15 | c.624G>T p.G208= | Silent (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- GPRASP2 | c.2286A>C p.S762= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, varscan2
- HNF1A | c.1140C>T p.V380= | Silent (SNP) | VAF 79/224 reads (35%) | catalogued as COSV57461491; called by muse, mutect2, varscan2
- HSPH1 | c.1482G>T p.T494= | Silent (SNP) | VAF 216/529 reads (41%) | called by muse, mutect2, varscan2
- IGHV1-18 | c.186A>G p.Q62= | Silent (SNP) | VAF 113/904 reads (13%) | catalogued as rs540331180; called by muse, mutect2, varscan2
- IGLL5 | c.309C>A p.T103= | Silent (SNP) | VAF 65/390 reads (17%) | catalogued as COSV101139023; called by muse, mutect2, varscan2
- IL22 | c.243C>T p.H81= | Silent (SNP) | VAF 60/374 reads (16%) | catalogued as rs1250418195, COSV100049013; called by muse, mutect2, varscan2
- ILF3 | c.582C>G p.P194= | Silent (SNP) | VAF 29/326 reads (9%) | called by muse, mutect2
- INA | c.243G>C p.A81= | Silent (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- INHBB | c.795G>A p.V265= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- KCTD15 | c.399G>T p.L133= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- KLHL34 | c.174C>T p.F58= | Silent (SNP) | VAF 68/142 reads (48%) | called by muse, mutect2, varscan2
- KNTC1 | c.5493T>G p.G1831= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- LEFTY2 | c.108G>A p.Q36= | Silent (SNP) | VAF 57/169 reads (34%) | catalogued as rs778815939; called by muse, mutect2, varscan2
- LRP4 | c.240T>C p.N80= | Silent (SNP) | VAF 99/653 reads (15%) | called by muse, mutect2, varscan2
- MEMO1 | c.516C>T p.L172= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV54457179; called by muse, mutect2, varscan2
- MRGPRX1 | c.99G>T p.L33= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- MSH6 | c.957G>A p.T319= | Silent (SNP) | VAF 97/603 reads (16%) | catalogued as rs375210430; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- MTSS1 | c.213G>A p.G71= | Silent (SNP) | VAF 121/404 reads (30%) | called by muse, mutect2, varscan2
- MX2 | c.663G>A p.L221= | Silent (SNP) | VAF 79/284 reads (28%) | called by muse, mutect2, varscan2
- MYH4 | c.5184C>A p.I1728= | Silent (SNP) | VAF 100/243 reads (41%) | called by muse, mutect2, varscan2
- NAA80 | c.696C>T p.A232= (on ENST00000417393 / NM_001200018.2; = p.A254= on NM_012191.4) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs781962043; called by muse, mutect2, varscan2
- NEFH | c.1137C>A p.A379= | Silent (SNP) | VAF 184/593 reads (31%) | catalogued as rs372676194, COSV60218876; called by muse, mutect2, varscan2
- NLRP2 | c.663G>T p.T221= | Silent (SNP) | VAF 111/370 reads (30%) | catalogued as COSV99672596; called by muse, mutect2, varscan2
- NSD1 | c.1005A>T p.P335= | Silent (SNP) | VAF 157/372 reads (42%) | called by muse, mutect2, varscan2
- OR1M1 | c.606G>T p.V202= | Silent (SNP) | VAF 79/360 reads (22%) | catalogued as rs746486487; called by muse, mutect2, varscan2
- OR2M4 | c.351C>A p.V117= | Silent (SNP) | VAF 54/336 reads (16%) | called by muse, varscan2
- OR4E2 | c.831G>T p.V277= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100330086; called by muse, mutect2, varscan2
- OR56A1 | c.111C>T p.L37= | Silent (SNP) | VAF 59/219 reads (27%) | catalogued as COSV57362389; called by muse, mutect2, varscan2
- OR5D13 | c.273C>T p.Y91= | Silent (SNP) | VAF 41/342 reads (12%) | catalogued as COSV62333996; called by muse, mutect2, varscan2
- PAM | c.1992G>A p.K664= | Silent (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- PCDHA1 | c.513G>T p.T171= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV65376098; called by muse, mutect2, varscan2
- PEPD | c.406C>T p.L136= | Silent (SNP) | VAF 122/626 reads (19%) | called by muse, mutect2, varscan2
- PKHD1 | c.4812G>T p.T1604= | Silent (SNP) | VAF 101/328 reads (31%) | catalogued as rs780533224; called by muse, mutect2, varscan2
- POLN | c.2112T>C p.A704= | Silent (SNP) | VAF 18/316 reads (6%) | called by muse, mutect2
- POLR1A | c.2127G>T p.A709= | Silent (SNP) | VAF 116/373 reads (31%) | catalogued as COSV55695618, COSV99806956; called by muse, mutect2, varscan2
- PRDM13 | c.1779G>A p.R593= | Silent (SNP) | VAF 31/504 reads (6%) | called by muse, mutect2
- PRKCG | c.1944G>A p.T648= | Silent (SNP) | VAF 10/208 reads (5%) | catalogued as COSV99668421; called by muse, mutect2
- PRPF6 | c.2475G>A p.Q825= | Silent (SNP) | VAF 138/384 reads (36%) | catalogued as COSV53874247; called by muse, mutect2, varscan2
- PXDN | c.1284C>T p.I428= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs768198520; called by muse, mutect2, varscan2
- RBPJL | c.363C>T p.C121= | Silent (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
- RIPOR3 | c.1530C>A p.G510= | Silent (SNP) | VAF 60/181 reads (33%) | catalogued as rs768013136; called by muse, mutect2, varscan2
- RNH1 | c.684G>T p.S228= | Silent (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- RYR3 | c.384C>A p.S128= | Silent (SNP) | VAF 70/308 reads (23%) | called by muse, mutect2, varscan2
- SCAF1 | c.2493G>A p.V831= | Silent (SNP) | VAF 51/173 reads (29%) | called by muse, mutect2, varscan2
- SELENOO | c.1470G>A p.L490= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV50563564; called by muse, mutect2, varscan2
- SERPINA1 | c.66C>T p.S22= | Silent (SNP) | VAF 183/499 reads (37%) | catalogued as rs764012079; called by muse, mutect2, varscan2
- SH3BP4 | c.1335G>T p.L445= | Silent (SNP) | VAF 155/355 reads (44%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.1446C>A p.A482= | Silent (SNP) | VAF 56/136 reads (41%) | called by muse, mutect2, varscan2
- SLC29A3 | c.429G>A p.L143= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- SLC9A8 | c.666C>A p.V222= | Silent (SNP) | VAF 48/395 reads (12%) | catalogued as rs753685668; called by muse, mutect2, varscan2
- SLCO1A2 | c.1140C>T p.F380= | Silent (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- TAF5L | c.477A>G p.L159= | Silent (SNP) | VAF 58/227 reads (26%) | called by muse, mutect2, varscan2
- TMEM184B | c.717G>T p.L239= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2
- TMEM71 | c.87G>A p.T29= | Silent (SNP) | VAF 102/349 reads (29%) | catalogued as COSV100785613; called by muse, mutect2, varscan2
- TRAPPC3 | c.162G>A p.R54= | Silent (SNP) | VAF 57/378 reads (15%) | called by muse, mutect2, varscan2
- TRIML1 | c.240G>A p.Q80= | Silent (SNP) | VAF 74/175 reads (42%) | called by muse, mutect2, varscan2
- UBE2O | c.2718C>G p.T906= | Silent (SNP) | VAF 33/268 reads (12%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.2685T>C p.S895= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- URB1 | c.4815C>T p.T1605= | Silent (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- USP13 | c.276G>T p.L92= | Silent (SNP) | VAF 18/465 reads (4%) | called by muse, mutect2
- USP13 | c.1014G>A p.L338= | Silent (SNP) | VAF 796/985 reads (81%) | called by muse, mutect2, varscan2
- USP44 | c.606A>G p.K202= | Silent (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2
- VANGL2 | c.507C>G p.R169= | Silent (SNP) | VAF 170/630 reads (27%) | called by muse, mutect2, varscan2
- WDR87 | c.1977C>T p.V659= | Silent (SNP) | VAF 107/407 reads (26%) | catalogued as COSV58200480; called by muse, mutect2, varscan2
- ZC2HC1C | c.1074C>A p.V358= | Silent (SNP) | VAF 78/338 reads (23%) | called by muse, mutect2, varscan2
- ZEB2 | c.2406T>A p.T802= | Silent (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2, varscan2
- ZFHX3 | c.3906C>A p.L1302= | Silent (SNP) | VAF 39/584 reads (7%) | called by muse, mutect2
- ZNF429 | c.1563C>A p.S521= | Silent (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- ZNF451 | c.507T>A p.I169= | Silent (SNP) | VAF 108/425 reads (25%) | called by muse, mutect2, varscan2
- ZNF527 | c.429G>A p.A143= | Silent (SNP) | VAF 34/338 reads (10%) | catalogued as rs754915502, COSV62230779; called by muse, mutect2, varscan2
- ZNF560 | c.2265T>C p.R755= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- ZNF98 | c.657T>C p.Y219= | Silent (SNP) | VAF 52/199 reads (26%) | called by muse, mutect2, varscan2
- ACHE | c.1723+179C>T | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- ADGRB2 | c.4572+16C>A | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2
- ANKRD20A8P | n.447A>C | RNA (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- AP004607.5 | n.214G>T | RNA (SNP) | VAF 45/346 reads (13%) | called by muse, mutect2, varscan2
- ARHGDIA | c.*419A>T | 3'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- ARL17B | c.525+1718A>T | Intron (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- BCAT1 | c.-2C>G | 5'UTR (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- CAPN3 | c.1914+21G>A | Intron (SNP) | VAF 199/463 reads (43%) | called by muse, mutect2, varscan2
- CCDC162P | n.5984C>A | RNA (SNP) | VAF 54/267 reads (20%) | called by muse, mutect2, varscan2
- CD99L2 | c.-52G>A | 5'UTR (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- CERS5 | c.872+108G>T | Intron (SNP) | VAF 46/142 reads (32%) | catalogued as rs148842982; called by muse, mutect2, varscan2
- CLK2P1 | n.1228C>T | RNA (SNP) | VAF 167/350 reads (48%) | called by muse, mutect2, varscan2
- CLUAP1 | c.-9C>T | 5'UTR (SNP) | VAF 45/235 reads (19%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*4482C>A | 3'UTR (SNP) | VAF 22/237 reads (9%) | called by muse, mutect2
- DNMT3B | c.-127G>C | 5'UTR (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- DST | c.4297-4038C>T | Intron (SNP) | VAF 65/404 reads (16%) | called by muse, mutect2, varscan2
- EIF4A2 | c.909+52A>G | Intron (SNP) | VAF 244/400 reads (61%) | catalogued as rs375043979; called by muse, mutect2, varscan2
- ENO1 | c.*1G>T | 3'UTR (SNP) | VAF 94/229 reads (41%) | called by muse, mutect2, varscan2
- EPHA6 | c.2574+1597C>A | Intron (SNP) | VAF 10/31 reads (32%) | catalogued as rs1049047255; called by muse, varscan2
- ETV1 | c.181+427G>A | Intron (SNP) | VAF 139/377 reads (37%) | called by muse, mutect2, varscan2
- FAM217A | c.-93G>T | 5'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- FARP1 | c.171+31142G>A | Intron (SNP) | VAF 37/304 reads (12%) | called by muse, mutect2, varscan2
- FTL | c.-18C>T | 5'UTR (SNP) | VAF 66/676 reads (10%) | catalogued as rs1048509386, COSV99509041; called by muse, mutect2
- FUZ | c.493-32T>A | Intron (SNP) | VAF 71/234 reads (30%) | called by muse, mutect2, varscan2
- GNLY | c.428-160C>A | Intron (SNP) | VAF 163/488 reads (33%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2535G>T | RNA (SNP) | VAF 59/1323 reads (4%) | called by muse, mutect2
- HERC2P3 | chr15:20453910 C>A | 5'Flank (SNP) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- KIF5A | c.2199-39C>A | Intron (SNP) | VAF 35/306 reads (11%) | catalogued as COSV54057548; called by muse, mutect2, varscan2
- LIPT2 | chr11:74497087 G>C | 5'Flank (SNP) | VAF 36/168 reads (21%) | called by muse, varscan2
- MDGA2 | c.2752+1523C>A | Intron (SNP) | VAF 32/265 reads (12%) | called by muse, mutect2, varscan2
- MECOM | c.-189-1188A>G | Intron (SNP) | VAF 476/571 reads (83%) | called by muse, mutect2, varscan2
- METAP1 | c.-19C>A | 5'UTR (SNP) | VAF 106/259 reads (41%) | called by muse, mutect2, varscan2
- MYO7B | c.3193-197G>T | Intron (SNP) | VAF 90/296 reads (30%) | called by muse, mutect2, varscan2
- MYOZ3 | c.217-9C>T | Intron (SNP) | VAF 71/155 reads (46%) | catalogued as rs746584047; called by muse, mutect2, varscan2
- NKX6-3 | c.*47C>A | 3'UTR (SNP) | VAF 50/173 reads (29%) | catalogued as rs1190134620; called by muse, mutect2, varscan2
- NOTCH2 | c.5002+38G>A | Intron (SNP) | VAF 114/1231 reads (9%) | catalogued as rs779298559; called by muse, mutect2
- NSG2 | c.*210C>G | 3'UTR (SNP) | VAF 55/371 reads (15%) | catalogued as COSV57458476; called by muse, mutect2, varscan2
- OBSCN | c.11659+4260A>G | Intron (SNP) | VAF 121/414 reads (29%) | catalogued as rs200710767; called by muse, mutect2, varscan2
- OR6W1P | n.605C>A | RNA (SNP) | VAF 108/207 reads (52%) | called by muse, mutect2, varscan2
- PCDH11X | n.568G>T | RNA (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- PDP1 | c.-186T>C | 5'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- PECR | c.-41G>A | 5'UTR (SNP) | VAF 118/301 reads (39%) | called by muse, mutect2, varscan2
- PHLDB1 | c.2380-450G>C | Intron (SNP) | VAF 19/123 reads (15%) | catalogued as rs185012325; called by muse, mutect2, varscan2
- PKD1L2 | n.1154dup | RNA (INS) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- POTEG | c.811-1039C>T | Intron (SNP) | VAF 56/727 reads (8%) | called by muse, varscan2
- PSKH2 | c.-12C>G | 5'UTR (SNP) | VAF 16/56 reads (29%) | catalogued as rs1455000422; called by muse, mutect2, varscan2
- RRN3P1 | n.2733A>T | RNA (SNP) | VAF 73/284 reads (26%) | called by muse, mutect2, varscan2
- SGSH | c.663+137C>T | Intron (SNP) | VAF 38/239 reads (16%) | catalogued as rs762657621; called by muse, mutect2, varscan2
- SHOC2 | c.-235+17440T>A | Intron (SNP) | VAF 87/468 reads (19%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1903+138G>A | Intron (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- SMOC1 | c.584-43C>G | Intron (SNP) | VAF 26/339 reads (8%) | catalogued as rs1211890264; called by muse, mutect2
- SMTN | c.2603+1041C>A | Intron (SNP) | VAF 47/176 reads (27%) | catalogued as COSV100294091; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.-13A>C | 5'UTR (SNP) | VAF 141/358 reads (39%) | called by muse, mutect2, varscan2
- STXBP2 | c.247-147G>A | Intron (SNP) | VAF 126/568 reads (22%) | catalogued as rs1312224805; called by muse, mutect2, varscan2
- TMCO1 | c.223+9G>T | Intron (SNP) | VAF 126/466 reads (27%) | catalogued as rs1267839255; called by mutect2, varscan2
- TPST2 | c.-160-10590C>T | Intron (SNP) | VAF 51/294 reads (17%) | catalogued as COSV100114045; called by muse, mutect2, varscan2
- VSTM2A | c.634+3786G>C | Intron (SNP) | VAF 115/540 reads (21%) | catalogued as rs894598174; called by muse, mutect2, varscan2
- ZFAND2A | chr7:1152297 A>G | 3'Flank (SNP) | VAF 8/166 reads (5%) | catalogued as rs1036221644, COSV100335779; called by muse, mutect2
- ZNF565 | c.256+61G>T | Intron (SNP) | VAF 67/372 reads (18%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+240G>T | Intron (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
